Gene-level copy-number profile of specimen HCM-BROD-1119-C43-85B from HCMI case HCM-BROD-1119-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Eye, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.0 years (26,307 days).
Specimen HCM-BROD-1119-C43-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f454231-8c62-4c00-a419-824091efa1db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1119-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/9efc06a4-e2db-4496-952c-f1eff83ed0bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,240; copy number 2: 51,763; copy number 3: 1,616; copy number 4: 1,202; copy number 5: 81; copy number 8: 14.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 95 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:42,879,616–43,288,258, 26 genes, copy number 5: RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1.
- chr7:38,239,580–38,330,935, 14 genes, copy number 8: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr14:22,132,553–22,501,663, 54 genes, copy number 5: TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 1,384. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
